Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8P3, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8P3-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

1 - "Hepato duodenal ligament":
Adipose tissue uninvolved by neoplasia.

2 - "Posterior hepatic":
Two lymph nodes uninvolved by neoplasia (0/2).

3 - "Right paracardic":
Muscles and adipose tissue uninvolved by neoplasia.

4 - "Splenic 11d":
Adipose and connective tissue uninvolved by neoplasia.

5 - "Margin of the esophagus":
Esophageal fragment uninvolved by neoplasia.

6 - "Gallbladder":
Chronic cholecystitis.

7 - "Stomach / omentum + lymphadenectomy":
Intestinal pattern adenocarcinoma, tubular moderately differentiated
Level of infiltration: perigastric adipose tissue.
Presence of satellite nodes in the adipose tissue.
Bormann Classification: Type III
Surgical resection margins uninvolved by neoplasia.
Angiolymphatic, and perineural invasion undetected.
Presence of lymph node metastasis in 1 of 7 resected of the lesser curvature (1/7).
Absence of lymph node metastasis in the greater curvature 5 (0/5).

ICD-O-3

Adenocarcinoma, tubular
8211/3

Site: Body of stomach
C16.2
7/3/14

APAX Discrepancy		☒
Final Metastasis/Status		☒
Case is (correction) ☒ DISQUALIFIED		

Source: NCI Genomic Data Commons file b746e144-4781-4cef-ba91-6a64c5c9bd51 (TCGA-VQ-A8P3.A7C2C2DF-F854-495F-ACC8-B0B06F773BF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).